Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A4YV, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A4YV-01A (Primary Tumor).

Patient: XXX

PESEL: : XXX

Age:

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion): **ca ventriculi**

Date of admission: (urgency: Standard)

Material:

1) Material: stomach, stomach with the tumour. Method of collection: Total organ resection

Histopathological Diagnosis:

Examination performed on:

(5% pN T35)

Tubular Invasive Adenocarcinoma of the stomach partially mucinous (G3), pT3, pN1
Cancer metastases in the lymph nodes No II/VII. (8140/3 T-63000)*

Macroscopic description:

Specimen consisting of the stomach, having been cut out along the greater curvature, sized 18.2 x 12.7 cm with the omentum sized 25 x 18 cm. Wall thickening sized 6.3 x 7.8 x 1.4 cm found in the pyloric region.

Microscopic description:

Adenocarcinoma tubuläre partim micinosum. et mucocellulare invasivum ventriculi.

Cancer invasion involves the whole thickness of the wall, infiltrates into the fat tissue and across the peritoneum.

(Mixed type acc. to 1 class.).

Tumour emboli in blood vessels.

The omentum - hyperaemia.

Incision lines in the cardia and intestine free of neoplastic lesions. Stomach off the tumour volume: Gastritis chronica.

Lymph nodes:

- (around cardia) - Lymphonodulitis reactiva No I.

3/ (lesser curvature): Metastases carcinomatosae in lymphonodis No (IW). Infiltratio carcinomatosae capsulae lymphonodorum et telae adiposae perinodalis.

- (peripyloric) - Lymphonodulitis reactiva No (II).

Assistant:

Pathologist:

Edited by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

1CD-0-3

adenocarcinoma, tubular 8211/3

CQCF Site: Stomach, intrum C16.3

Path Stomach, C16.9

11/4/12

HPA Discrepancy		
Case is (check):		

Source: NCI Genomic Data Commons file 9018f9c0-9238-4393-bb01-d6a25b232e39 (TCGA-D7-A4YV.15C5077B-D963-41F4-B8FD-6646C656DDCC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).